Gene-level copy-number profile of tumor specimen TCGA-CG-4466-01A from TCGA case TCGA-CG-4466, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 81.4 years (29,739 days).
Specimen TCGA-CG-4466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5ec80c72-f3f6-4718-8c12-fa03cafbec1a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4466-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5aa38173-d011-4f64-8e91-db3f47d8db94

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 27; copy number 2: 7,680; copy number 3: 17,139; copy number 4: 26,425; copy number 5: 3,368; copy number 6: 2,065; copy number 7: 2,611; copy number 8: 395; copy number 9: 9; copy number 39: 3; copy number 40: 4; copy number 42: 1; copy number 44: 19; copy number 49: 54; copy number 54: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4466-01A-01D-1155-01): tumor purity 0.79, ploidy 3.74, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 97 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:92,540,268–92,917,187, 7 genes, copy number 54 (within-gene range 4–54): AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr8:41,929,479–42,271,266, 9 genes, copy number 9: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1.
- chr17:37,686,431–37,745,105, 1 gene, copy number 42: HNF1B.
- chr17:39,637,090–39,864,312, 9 genes, copy number 40–49 (within-gene range 4–49): STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3.
- chr17:40,473,554–41,329,545, 68 genes, copy number 44–49 (within-gene range 4–49) (broad region; genes not listed).
- chr17:41,712,331–41,734,644, 3 genes, copy number 39: GAST, HAP1, RNA5SP442.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
